Gene-level copy-number profile of tumor specimen TCGA-BR-A4CR-01A from TCGA case TCGA-BR-A4CR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.3 years (25,669 days).
Specimen TCGA-BR-A4CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b005530c-5b3b-4fe8-b39b-6f353c4b7115.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4CR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/038d91bd-3819-44b3-843e-dbfa8570e89f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 54; copy number 2: 19,516; copy number 3: 21,203; copy number 4: 12,257; copy number 5: 1,494; copy number 6: 2,705; copy number 7: 241; copy number 8: 120; copy number 9: 1,338; copy number 10: 711; copy number 12: 7; copy number 13: 4; copy number 14: 10; copy number 16: 8; copy number 18: 29; copy number 22: 4; copy number 25: 5; copy number 29: 19; copy number 30: 9; copy number 36: 30; copy number 37: 12; copy number 38: 1; copy number 40: 21; copy number 42: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4CR-01A-11D-A24C-01): tumor purity 0.77, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,380,476–7,004,112, 7 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,570 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:159,318,979–160,062,615, 15 genes, copy number 7: BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2, PLA2R1.
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr8:38,996,754–39,105,445, 1 gene, copy number 16 (within-gene range 2–16): ADAM9.
- chr8:39,106,990–39,310,443, 3 genes, copy number 16: ADAM32, RPL3P10, AC105185.1.
- chr8:40,104,169–40,172,612, 4 genes, copy number 13: AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:43,372,559–43,540,927, 8 genes, copy number 7: AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P.
- chr8:71,895,991–71,896,330, 1 gene, copy number 42: RPS20P20.
- chr8:85,826,865–87,868,607, 30 genes, copy number 36: REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1.
- chr8:99,613,783–99,895,121, 6 genes, copy number 25–38: RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1.
- chr8:102,864,271–103,002,424, 1 gene, copy number 18 (within-gene range 3–18): MAILR.
- chr8:102,950,467–104,256,094, 28 genes, copy number 12–18 (within-gene range 8–18): Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1.
- chr8:104,339,087–104,356,689, 1 gene, copy number 8: DCSTAMP.
- chr8:112,148,742–113,436,939, 5 genes, copy number 10–22 (within-gene range 4–40): RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:124,998,497–131,144,948, 82 genes, copy number 14–40 (within-gene range 3–40) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7–9 (broad region; genes not listed).
- chr20:87,250–13,996,443, 281 genes, copy number 7–8 (broad region; genes not listed).
- chr20:14,003,508–14,223,325, 3 genes, copy number 8: RPS3P1, AIMP1P1, RN7SL864P.

Autosomal genes at a single copy (total copy number 1): 54. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
